Somatic mutation profile of tumor specimen ALCH-ADSW-TTP1-A (aliquot ALCH-ADSW-TTP1-A-1-0-D-A581-36) from ALCHEMIST case ALCH-ADSW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 62.5 years (22,828 days).
Specimen ALCH-ADSW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 059c04e2-022a-49a5-bafb-ffc088b04c8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADSW-NB1-A (Blood Derived Normal), aliquot ALCH-ADSW-NB1-A-1-0-D-A581-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8db034b3-aef7-466a-b821-25a30b87a832

The open-access MAF lists 511 somatic variants for this specimen: 351 protein-altering or splice-affecting, 91 silent, 69 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 308, Silent 91, Intron 34, Nonsense Mutation 16, 3'UTR 13, RNA 13, Splice Site 12, Splice Region 7, Frame Shift Del 7, 5'UTR 6, 5'Flank 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1435G>T p.D479Y | Missense Mutation (SNP) | VAF 30/586 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66706780, COSV66707774; called by muse, mutect2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 115/1081 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OTOF | c.4227+1G>T p.X1409_splice (on ENST00000272371 / NM_194248.3; = p.X642_splice on NM_004802.4) | Splice Site (SNP) | VAF 34/570 reads (6%) | catalogued as rs397515601, CS083957; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 84/404 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, varscan2
- ABCA1 | c.1972G>T p.G658C | Missense Mutation (SNP) | VAF 36/424 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV101036666; called by muse, mutect2
- ABCC12 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 52/963 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV60916719; called by muse, mutect2
- ADAMTS18 | c.1184G>C p.C395S | Missense Mutation (SNP) | VAF 112/1240 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99031666; called by muse, mutect2
- ADCY1 | c.2689C>A p.L897I | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52038291; called by muse, mutect2, varscan2
- ADCY8 | c.619C>A p.P207T | Missense Mutation (SNP) | VAF 16/388 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as rs926711426; called by muse, mutect2
- AFF2 | c.2830G>C p.A944P | Missense Mutation (SNP) | VAF 78/1174 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV54000532; called by muse, mutect2
- AGBL3 | c.1561G>A p.V521I | Missense Mutation (SNP) | VAF 69/665 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs1311200916, COSV51951778; called by muse, mutect2
- AHCTF1 | c.2156A>G p.D719G (on ENST00000366508; = p.D693G on NM_015446.5) | Missense Mutation (SNP) | VAF 64/609 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58250941; called by muse, mutect2, varscan2
- ALPK2 | c.1645C>A p.P549T | Missense Mutation (SNP) | VAF 34/767 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as COSV64491303; called by muse, mutect2
- AOX1 | c.3494G>C p.G1165A | Missense Mutation (SNP) | VAF 19/589 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV99613570; called by muse, mutect2
- BICC1 | c.2785G>T p.A929S | Missense Mutation (SNP) | VAF 52/464 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs775497601; called by muse, mutect2, varscan2
- BRINP2 | c.461-2A>T p.X154_splice | Splice Site (SNP) | VAF 103/1260 reads (8%) | catalogued as COSV64177968; called by muse, mutect2
- BRIP1 | c.2512G>T p.D838Y | Missense Mutation (SNP) | VAF 104/805 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52000614; called by muse, varscan2
- C1QTNF2 | c.906C>A p.N302K (on ENST00000393975; = p.N257K on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/412 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101220893; called by muse, mutect2
- CCDC168 | c.17794G>A p.G5932R | Missense Mutation (SNP) | VAF 19/384 reads (5%) | SIFT tolerated (0.97); PolyPhen probably damaging (1); catalogued as COSV59422063; called by muse, mutect2
- CCDC190 | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 29/301 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as rs1156682454; called by muse, mutect2
- CELA1 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 48/514 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs752403727; called by muse, mutect2
- CHL1 | c.636G>T p.R212S | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV56602284; called by muse, mutect2
- CLN3 | c.250A>T p.T84S (on ENST00000360019 / NM_001286104.2; = p.T108S on NM_000086.2) | Missense Mutation (SNP) | VAF 58/551 reads (11%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.9); catalogued as rs1302804526; called by muse, mutect2, varscan2
- CRB1 | c.2213G>T p.S738I | Missense Mutation (SNP) | VAF 40/345 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.178); catalogued as rs747700125; called by muse, mutect2, varscan2
- CSMD1 | c.7253C>G p.A2418G (on ENST00000520002; = p.A2417G on NM_033225.6) | Missense Mutation (SNP) | VAF 20/513 reads (4%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.829); catalogued as COSV100144566; called by muse, mutect2
- DACH2 | c.1760A>G p.Y587C | Missense Mutation (SNP) | VAF 48/605 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.187); catalogued as COSV100913937; called by muse, mutect2
- DNAH9 | c.4103G>T p.S1368I | Missense Mutation (SNP) | VAF 34/320 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV99304275; called by muse, mutect2, varscan2
- DPH7 | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 7/135 reads (5%) | catalogued as rs1446974541; called by muse, mutect2
- DST | c.19465A>G p.M6489V (on ENST00000361203 / NM_001374722.1; = p.M4186V on NM_015548.5) | Missense Mutation (SNP) | VAF 30/482 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs748600276, COSV55035718; called by muse, mutect2
- ELOVL4 | c.897G>T p.M299I | Missense Mutation (SNP) | VAF 28/972 reads (3%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV63953733; called by muse, mutect2
- F8 | c.6785T>A p.V2262E | Missense Mutation (SNP) | VAF 68/856 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as CM080308; called by muse, mutect2
- FAT4 | c.8320A>T p.R2774W | Missense Mutation (SNP) | VAF 48/643 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1267410504; called by muse, mutect2
- FCRL5 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.141); catalogued as rs757938999, COSV62516784; called by muse, mutect2
- FEZ1 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 46/557 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV54030658; called by muse, mutect2
- FMN2 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.061); catalogued as rs766875636, COSV100144826; called by muse, mutect2, varscan2
- GABRA2 | c.641G>C p.R214T | Missense Mutation (SNP) | VAF 24/812 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62911972, COSV62913356; called by muse, mutect2
- GABRB1 | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.249); catalogued as COSV54981989; called by muse, varscan2
- GRID2 | c.1204G>T p.G402* | Nonsense Mutation (SNP) | VAF 42/770 reads (5%) | catalogued as rs1407346425, COSV56237867; called by muse, mutect2
- GRM3 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 63/758 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100862005; called by muse, mutect2
- HCN1 | c.606C>A p.D202E | Missense Mutation (SNP) | VAF 95/589 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV57495230; called by muse, mutect2, varscan2
- HIPK2 | c.2231G>T p.G744V | Missense Mutation (SNP) | VAF 69/466 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV100702316; called by muse, mutect2, varscan2
- IFI30 | c.290C>A p.T97K | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55850075; called by muse, mutect2, varscan2
- ITGA10 | c.2605G>T p.A869S | Missense Mutation (SNP) | VAF 36/450 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.24); catalogued as COSV100994923; called by muse, mutect2
- ITGA8 | c.1525G>C p.V509L | Missense Mutation (SNP) | VAF 57/424 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65236719; called by muse, mutect2, varscan2
- KCNH7 | c.116G>T p.C39F | Missense Mutation (SNP) | VAF 92/561 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs1166460826, COSV59812000; called by muse, mutect2, varscan2
- KIF1C | c.2129G>T p.R710L | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.145); catalogued as COSV100296998, COSV57908546; called by muse, mutect2
- LAMA2 | c.3718C>G p.Q1240E | Missense Mutation (SNP) | VAF 47/844 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as CM950741; called by muse, mutect2
- LGALS7B | c.145C>A p.L49M | Missense Mutation (SNP) | VAF 86/850 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV59252026; called by muse, mutect2
- LPA | c.5564G>T p.W1855L | Missense Mutation (SNP) | VAF 42/924 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60313548; called by muse, mutect2
- MAGEC1 | c.1878G>T p.Q626H | Missense Mutation (SNP) | VAF 25/250 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV53568950; called by muse, mutect2, varscan2
- MAGEC1 | c.2147A>T p.E716V | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.062); catalogued as COSV99596630; called by muse, mutect2
- MCF2L2 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 21/243 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV100192439; called by muse, mutect2
- MFN2 | c.1568C>G p.S523C | Missense Mutation (SNP) | VAF 181/1025 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV52425677; called by muse, mutect2, varscan2
- MGAM | c.3952C>A p.P1318T | Missense Mutation (SNP) | VAF 36/342 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72073668; called by muse, mutect2, varscan2
- MMP16 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 30/538 reads (6%) | catalogued as COSV54182752; called by muse, mutect2
- MYO1H | c.1008C>A p.H336Q | Missense Mutation (SNP) | VAF 23/470 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.868); catalogued as COSV100183430; called by muse, mutect2
- NEU1 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 30/524 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1263545300, COSV57666522; called by muse, mutect2
- NEU2 | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV52091786; called by muse, mutect2
- NGF | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 59/415 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65687985; called by muse, mutect2, varscan2
- NLRC4 | c.1339C>A p.Q447K | Missense Mutation (SNP) | VAF 20/454 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV61591849; called by muse, mutect2
- NOD2 | c.2773G>T p.D925Y | Missense Mutation (SNP) | VAF 59/704 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV56054666; called by muse, mutect2
- OR2A12 | c.167C>G p.T56R | Missense Mutation (SNP) | VAF 16/524 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV68821245; called by muse, mutect2
- OR2D2 | c.88G>T p.V30L | Missense Mutation (SNP) | VAF 30/362 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs113796560, COSV55057117; called by muse, mutect2
- OR2L5 | c.332C>A p.A111E | Missense Mutation (SNP) | VAF 45/942 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as rs756291968, COSV62365393; called by muse, mutect2
- OR51L1 | c.709C>A p.L237I | Missense Mutation (SNP) | VAF 51/214 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as COSV100386361; called by muse, mutect2, varscan2
- OR51Q1 | c.242C>A p.P81H | Missense Mutation (SNP) | VAF 18/303 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV56177805; called by muse, mutect2
- OR5F1 | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 36/349 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs749693017, COSV53545976; called by muse, mutect2, varscan2
- OR6B3 | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 32/231 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100097414; called by muse, mutect2, varscan2
- OR9A2 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 104/580 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1357714613; called by muse, mutect2, varscan2
- P3H2 | c.956-7C>T | Splice Region (SNP) | VAF 95/1500 reads (6%) | catalogued as rs1300049335; called by muse, mutect2
- PANK4 | c.1048G>C p.A350P | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.166); catalogued as COSV65866446; called by muse, mutect2
- PCDHA3 | c.1287C>A p.D429E | Missense Mutation (SNP) | VAF 45/517 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV63543404; called by muse, mutect2
- PCDHB2 | c.1961G>T p.R654L | Missense Mutation (SNP) | VAF 48/410 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as COSV50635923; called by muse, mutect2, varscan2
- PFKFB1 | c.715C>A p.R239S | Missense Mutation (SNP) | VAF 66/683 reads (10%) | PolyPhen probably damaging (0.992); catalogued as COSV66629305; called by muse, mutect2
- PGK2 | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 32/499 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV100505719; called by muse, mutect2
- PIEZO2 | c.4123G>A p.V1375M | Missense Mutation (SNP) | VAF 23/647 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs947854422; called by muse, mutect2
- PIWIL1 | c.653G>T p.R218M | Missense Mutation (SNP) | VAF 30/399 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs756720678, COSV55348805; called by muse, mutect2
- PKD1L1 | c.7493C>T p.T2498M | Missense Mutation (SNP) | VAF 107/659 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.667); catalogued as rs367611487; called by muse, mutect2, varscan2
- POTED | c.1516C>G p.Q506E | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV55046362; called by muse, mutect2, varscan2
- PRLHR | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV53303172; called by muse, mutect2
- PRR23A | c.689C>A p.P230H | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101270253; called by muse, mutect2
- PSG9 | c.277C>A p.P93T | Missense Mutation (SNP) | VAF 90/590 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV52487200; called by muse, mutect2, varscan2
- PTCH1 | c.3214G>T p.G1072C | Missense Mutation (SNP) | VAF 43/662 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779857568; called by muse, mutect2
- PTGS1 | c.157C>A p.R53S | Missense Mutation (SNP) | VAF 38/404 reads (9%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as rs767143547, COSV99792782; called by muse, mutect2
- PUS7L | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 24/416 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.73); catalogued as rs1362772729, COSV100786513; called by muse, mutect2
- PXDNL | c.2287G>T p.A763S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100685661; called by mutect2, varscan2
- QPCT | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 243/1281 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376794569; called by muse, mutect2, varscan2
- RBM6 | c.245A>G p.H82R | Missense Mutation (SNP) | VAF 36/304 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1427667954; called by muse, mutect2, varscan2
- ROBO4 | c.2785G>A p.V929I | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs370405639; called by muse, mutect2, varscan2
- RYR2 | c.409C>G p.R137G | Missense Mutation (SNP) | VAF 41/776 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV63699626; called by muse, mutect2
- SCN2A | c.4940G>T p.R1647L | Missense Mutation (SNP) | VAF 84/717 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV51849555; called by muse, mutect2, varscan2
- SFMBT1 | c.758A>T p.E253V | Missense Mutation (SNP) | VAF 48/596 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV56252097; called by muse, mutect2
- SLC27A6 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 52/454 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201193988, COSV52479088; called by muse, mutect2, varscan2
- SLC9A9 | c.984G>T p.E328D | Missense Mutation (SNP) | VAF 56/884 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs189441040; called by muse, mutect2
- SOS2 | c.1279A>G p.I427V | Missense Mutation (SNP) | VAF 83/585 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as rs1486131664; called by muse, mutect2, varscan2
- SRC | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 62/464 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.577); catalogued as COSV100658001; called by muse, mutect2, varscan2
- STK35 | c.1174G>T p.A392S | Missense Mutation (SNP) | VAF 40/596 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.03); catalogued as rs184806500; called by muse, mutect2
- TBC1D22B | c.427A>C p.T143P | Missense Mutation (SNP) | VAF 95/684 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV65142675; called by muse, mutect2, varscan2
- THEMIS | c.785A>G p.N262S | Missense Mutation (SNP) | VAF 19/273 reads (7%) | SIFT tolerated (0.89); PolyPhen benign (0.018); catalogued as rs369097146; called by muse, mutect2
- TMEM70 | c.371A>G p.Y124C | Missense Mutation (SNP) | VAF 38/571 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1489913650, COSV56487230; called by muse, mutect2
- TMTC1 | c.2438G>A p.R813K (on ENST00000539277 / NM_001193451.2; = p.R705K on NM_175861.3) | Missense Mutation (SNP) | VAF 19/442 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs993180516, COSV55483058; called by muse, mutect2
- TUBB8 | c.184C>A p.R62S | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV59117070; called by muse, mutect2
- WSCD1 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58494674; called by muse, mutect2
- XIRP2 | c.2092C>T p.Q698* (on ENST00000628543; = p.Q873* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 53/524 reads (10%) | catalogued as rs140766135, COSV54686868; called by muse, mutect2, varscan2
- ZFAND4 | c.394del p.E132Rfs*20 | Frame Shift Del (DEL) | VAF 47/477 reads (10%) | catalogued as COSV58897234; called by mutect2, pindel
- ZNF142 | c.2030G>T p.R677L (on ENST00000411696 / NM_001379660.1; = p.R477L on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as COSV101376949; called by muse, mutect2, varscan2
- ZNF208 | c.539G>T p.R180I | Missense Mutation (SNP) | VAF 40/519 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV68105467; called by muse, mutect2
- ZNF277 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 42/387 reads (11%) | catalogued as rs1202955540; called by muse, mutect2, varscan2
- AARS1 | c.539A>T p.D180V | Missense Mutation (SNP) | VAF 41/230 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ABCA1 | c.1971G>T p.K657N | Missense Mutation (SNP) | VAF 35/423 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCC6 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.288); called by mutect2, varscan2
- ABCD2 | c.1843C>A p.Q615K | Missense Mutation (SNP) | VAF 58/575 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AC231657.3 | c.634C>A p.H212N | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, varscan2
- ADAM20 | c.1237C>A p.L413I | Missense Mutation (SNP) | VAF 30/450 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2
- ADAMTSL3 | c.1701-1G>T p.X567_splice | Splice Site (SNP) | VAF 20/126 reads (16%) | called by muse, mutect2
- ADGRB2 | c.2113G>A p.V705M | Missense Mutation (SNP) | VAF 25/419 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ADGRL4 | c.1768G>A p.G590R | Missense Mutation (SNP) | VAF 110/996 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- AGAP6 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 61/797 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- AGBL2 | c.1108G>T p.G370W | Missense Mutation (SNP) | VAF 137/579 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- AMPH | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 12/366 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- ANK2 | c.3745A>T p.N1249Y | Missense Mutation (SNP) | VAF 54/1502 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- ANO4 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 26/515 reads (5%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.857); called by muse, mutect2
- AOAH | c.92C>A p.S31Y | Missense Mutation (SNP) | VAF 112/712 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARMC4 | c.1783G>T p.A595S | Missense Mutation (SNP) | VAF 40/403 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2
- ATP8B2 | c.1386+1G>A p.X462_splice (on ENST00000672630; = p.X429_splice on NM_001367934.1 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 72/622 reads (12%) | called by muse, mutect2, varscan2
- AWAT2 | c.633G>T p.M211I | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- BAHCC1 | c.3047G>C p.C1016S | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.121); called by muse, mutect2
- C1QA | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 58/614 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2
- CACNA1A | c.1621C>T p.L541F | Missense Mutation (SNP) | VAF 84/499 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CACNA1H | c.1618G>T p.G540C | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2
- CACNA2D3 | c.1213G>T p.D405Y | Missense Mutation (SNP) | VAF 36/508 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2
- CARD9 | c.1112A>G p.H371R | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2
- CDH2 | c.2535T>G p.N845K | Missense Mutation (SNP) | VAF 59/540 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- CDH20 | c.1736G>A p.S579N | Missense Mutation (SNP) | VAF 26/448 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- CDH6 | c.775A>C p.T259P | Missense Mutation (SNP) | VAF 41/570 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2
- CDHR5 | c.2403C>A p.N801K (on ENST00000358353 / NM_001171968.2; = p.N807K on NM_021924.5) | Missense Mutation (SNP) | VAF 51/259 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CELSR2 | c.6193C>T p.H2065Y | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CFAP126 | c.422C>A p.P141Q | Missense Mutation (SNP) | VAF 121/911 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- CFAP161 | c.338T>A p.L113Q | Missense Mutation (SNP) | VAF 54/474 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- CGAS | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CHCHD3 | c.452G>T p.R151M | Missense Mutation (SNP) | VAF 101/688 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLCN1 | c.2627C>G p.S876C | Missense Mutation (SNP) | VAF 55/554 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CLEC5A | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 88/684 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- CNGA1 | c.1959A>T p.Q653H | Missense Mutation (SNP) | VAF 73/1162 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2
- COL3A1 | c.3116C>A p.S1039Y | Missense Mutation (SNP) | VAF 182/1177 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- COL4A6 | c.604G>C p.G202R | Missense Mutation (SNP) | VAF 42/442 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPB1 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 26/441 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- CPSF6 | c.1449G>T p.K483N | Missense Mutation (SNP) | VAF 39/487 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- CPZ | c.1544G>T p.G515V (on ENST00000360986 / NM_001014447.3; = p.G504V on NM_003652.3) | Missense Mutation (SNP) | VAF 41/333 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CREB3L3 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 45/310 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CREBBP | c.4351C>T p.H1451Y | Missense Mutation (SNP) | VAF 94/873 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CTPS2 | c.1094+1G>T p.X365_splice | Splice Site (SNP) | VAF 47/823 reads (6%) | called by muse, mutect2
- CUBN | c.5927G>T p.G1976V | Missense Mutation (SNP) | VAF 26/778 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- CUTC | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 123/1195 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- DACH2 | c.203G>C p.C68S | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- DCAF17 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 33/1246 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DCLRE1C | c.540G>A p.E180= (on ENST00000378278 / NM_001350965.2; = p.E65= on NM_022487.4) | Splice Region (SNP) | VAF 48/1051 reads (5%) | called by muse, mutect2
- DDX60L | c.5057G>T p.S1686I | Missense Mutation (SNP) | VAF 59/530 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.349); called by muse, varscan2
- DGKI | c.2657del p.P886Lfs*8 | Frame Shift Del (DEL) | VAF 31/304 reads (10%) | called by mutect2, pindel, varscan2
- DLC1 | c.2005A>T p.K669* (on ENST00000276297 / NM_001348081.2; = p.K232* on NM_006094.5) | Nonsense Mutation (SNP) | VAF 13/404 reads (3%) | called by muse, mutect2
- DNAH9 | c.998C>A p.P333H | Missense Mutation (SNP) | VAF 71/459 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- DPY19L3 | c.851T>C p.V284A | Missense Mutation (SNP) | VAF 37/903 reads (4%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2
- DSCAM | c.3769T>A p.Y1257N | Missense Mutation (SNP) | VAF 30/550 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- DSG4 | c.658A>G p.T220A | Missense Mutation (SNP) | VAF 128/1023 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ELAVL4 | c.542A>T p.D181V | Missense Mutation (SNP) | VAF 83/515 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENAM | c.1502C>A p.S501Y | Missense Mutation (SNP) | VAF 72/898 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- ESPL1 | c.4036A>T p.T1346S | Missense Mutation (SNP) | VAF 24/401 reads (6%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.886); called by muse, mutect2
- F2R | c.1160G>T p.C387F | Missense Mutation (SNP) | VAF 83/808 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- FAM120C | c.2214G>C p.R738S | Missense Mutation (SNP) | VAF 50/508 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- FAM13A | c.876G>T p.Q292H | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- FAM181A | c.944C>G p.A315G | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- FERD3L | c.248del p.G83Efs*7 | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | called by mutect2, pindel
- FGFR4 | c.30_31del p.L11Afs*15 | Frame Shift Del (DEL) | VAF 18/135 reads (13%) | called by mutect2, pindel, varscan2
- FLG2 | c.1868C>G p.S623C | Missense Mutation (SNP) | VAF 117/1004 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- FLNA | c.2534G>T p.S845I | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); called by muse, mutect2
- FOXC1 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- FOXD4L1 | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 78/1125 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); called by muse, mutect2
- FREM2 | c.4043G>A p.G1348E | Missense Mutation (SNP) | VAF 70/1489 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.005); called by muse, mutect2
- FSIP2 | c.4406A>T p.N1469I | Missense Mutation (SNP) | VAF 36/796 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.316); called by muse, mutect2
- FTSJ1 | c.655+1G>T p.X219_splice | Splice Site (SNP) | VAF 38/537 reads (7%) | called by muse, mutect2
- FTSJ1 | c.688C>A p.R230S | Missense Mutation (SNP) | VAF 20/578 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.119); called by muse, mutect2
- GABRA5 | c.732C>A p.Y244* | Nonsense Mutation (SNP) | VAF 50/241 reads (21%) | called by muse, mutect2, varscan2
- GABRE | c.444C>A p.S148R | Missense Mutation (SNP) | VAF 38/444 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); called by muse, mutect2
- GDPD2 | c.304-1G>T p.X102_splice | Splice Site (SNP) | VAF 36/400 reads (9%) | called by muse, mutect2
- GFM1 | c.2114C>T p.S705L | Missense Mutation (SNP) | VAF 98/1115 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- GIMAP7 | c.600C>G p.Y200* | Nonsense Mutation (SNP) | VAF 160/1227 reads (13%) | called by muse, mutect2, varscan2
- GOLGB1 | c.7949C>G p.S2650C | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.855); called by muse, mutect2
- GP2 | c.981A>T p.K327N (on ENST00000381362 / NM_001007240.3; = p.K324N on NM_001502.4) | Missense Mutation (SNP) | VAF 43/452 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.139); called by muse, mutect2
- GPR148 | c.759del p.Q254Rfs*11 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel
- GPRIN2 | c.276C>G p.S92R | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- GSPT2 | c.723A>T p.E241D | Missense Mutation (SNP) | VAF 76/886 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); called by muse, mutect2
- HECW1 | c.853G>C p.D285H | Missense Mutation (SNP) | VAF 80/478 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HHLA1 | c.590-1G>A p.X197_splice | Splice Site (SNP) | VAF 88/490 reads (18%) | called by muse, mutect2, varscan2
- HOXB3 | c.797del p.P266Rfs*11 | Frame Shift Del (DEL) | VAF 24/136 reads (18%) | called by pindel, varscan2*
- IGFBP3 | c.675G>T p.K225N | Missense Mutation (SNP) | VAF 103/694 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- IGLV8-61 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 30/331 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.132); called by muse, mutect2
- IGSF1 | c.3779G>T p.G1260V | Missense Mutation (SNP) | VAF 18/489 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- IL11RA | c.811-2A>T p.X271_splice | Splice Site (SNP) | VAF 59/532 reads (11%) | called by muse, mutect2, varscan2
- IL1RAPL1 | c.1871A>T p.Y624F | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNH1 | c.2713C>A p.P905T (on ENST00000271751 / NM_172362.3; = p.P878T on NM_002238.4) | Missense Mutation (SNP) | VAF 91/565 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- KCNN2 | c.711G>T p.W237C (on ENST00000264773; = p.W449C on NM_021614.4) | Missense Mutation (SNP) | VAF 48/645 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- KIAA0100 | c.2440A>T p.N814Y | Missense Mutation (SNP) | VAF 92/570 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIF4B | c.3501G>T p.K1167N | Missense Mutation (SNP) | VAF 36/488 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.838); called by muse, mutect2
- KITLG | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 43/685 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2
- KLHL34 | c.1058C>A p.P353H | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- KRT32 | c.164C>T p.T55I | Missense Mutation (SNP) | VAF 61/374 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KRTAP7-1 | c.7C>A p.R3S | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.427); called by muse, mutect2
- L3MBTL3 | c.2315C>A p.A772E | Missense Mutation (SNP) | VAF 58/1006 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- LANCL3 | c.868C>A p.L290M | Missense Mutation (SNP) | VAF 53/694 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LINC01098 | n.623G>T | Splice Region (SNP) | VAF 41/345 reads (12%) | called by muse, mutect2, varscan2
- LINGO2 | c.1201C>T p.L401F | Missense Mutation (SNP) | VAF 44/600 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.783); called by muse, mutect2
- LLCFC1 | c.38A>T p.H13L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- LMOD1 | c.1779G>A p.V593= | Splice Region (SNP) | VAF 15/273 reads (5%) | called by muse, mutect2
- LPA | c.5565G>C p.W1855C | Missense Mutation (SNP) | VAF 41/932 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRBA | c.6018A>T p.E2006D | Missense Mutation (SNP) | VAF 45/432 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- LRP1B | c.3017G>A p.C1006Y | Missense Mutation (SNP) | VAF 44/336 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAGEA12 | c.276G>T p.Q92H | Missense Mutation (SNP) | VAF 33/359 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.218); called by muse, mutect2
- MAMLD1 | c.988G>T p.G330C | Missense Mutation (SNP) | VAF 17/315 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- MAP3K15 | c.291C>A p.H97Q | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- MARCHF11 | c.869T>C p.M290T | Missense Mutation (SNP) | VAF 29/330 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- MAT2B | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 51/780 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MED12L | c.762G>A p.W254* | Nonsense Mutation (SNP) | VAF 42/728 reads (6%) | called by muse, mutect2
- MFSD8 | c.68G>T p.W23L | Missense Mutation (SNP) | VAF 42/381 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MRC1 | c.2035T>A p.F679I | Missense Mutation (SNP) | VAF 167/958 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MROH2A | c.2013C>A p.N671K | Missense Mutation (SNP) | VAF 15/452 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.076); called by muse, mutect2
- MTHFD1 | c.560G>A p.W187* | Nonsense Mutation (SNP) | VAF 44/1033 reads (4%) | called by muse, mutect2
- MUC12 | c.15921G>T p.K5307N (on ENST00000379442; = p.K5164N on NM_001164462.1) | Missense Mutation (SNP) | VAF 65/274 reads (24%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- MUC16 | c.37939G>T p.G12647C | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MUC17 | c.8213G>T p.G2738V | Missense Mutation (SNP) | VAF 11/247 reads (4%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.972); called by muse, mutect2
- MXRA5 | c.6644A>C p.D2215A | Missense Mutation (SNP) | VAF 13/439 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MYBPC3 | c.1784T>A p.I595N | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- MYH1 | c.742G>T p.G248C | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYH2 | c.2296C>A p.H766N | Missense Mutation (SNP) | VAF 88/1421 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.076); called by muse, mutect2
- MYH7 | c.897C>T p.D299= | Splice Region (SNP) | VAF 151/546 reads (28%) | called by muse, mutect2, varscan2
- MYO10 | c.2699T>C p.L900P | Missense Mutation (SNP) | VAF 22/504 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NAA10 | c.364T>A p.Y122N | Missense Mutation (SNP) | VAF 26/577 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NCKAP1L | c.350G>A p.C117Y | Missense Mutation (SNP) | VAF 47/848 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- NEO1 | c.2264T>C p.V755A | Missense Mutation (SNP) | VAF 16/360 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- NKRF | c.389C>A p.A130D | Missense Mutation (SNP) | VAF 42/666 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.035); called by muse, mutect2
- NRCAM | c.3298T>C p.Y1100H | Missense Mutation (SNP) | VAF 38/345 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- NRK | c.3470C>G p.S1157C | Missense Mutation (SNP) | VAF 20/241 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, mutect2
- NUBPL | c.291+1G>A p.X97_splice | Splice Site (SNP) | VAF 55/1213 reads (5%) | called by muse, mutect2
- NYX | c.1102G>T p.V368L | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.668); called by muse, mutect2
- OBSL1 | c.1980G>T p.E660D | Missense Mutation (SNP) | VAF 56/450 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- OR2F2 | c.616C>A p.L206I | Missense Mutation (SNP) | VAF 135/749 reads (18%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- OR4C12 | c.636G>T p.L212F | Missense Mutation (SNP) | VAF 48/562 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2
- OR4K13 | c.579C>A p.Y193* | Nonsense Mutation (SNP) | VAF 90/373 reads (24%) | called by muse, mutect2, varscan2
- PAXBP1 | c.2635A>T p.R879W | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2
- PCDHB9 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHB9 | c.1747G>T p.G583C | Missense Mutation (SNP) | VAF 45/556 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA2 | c.1486G>T p.V496F | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); called by muse, mutect2
- PCSK1N | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE4B | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 30/773 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.745); called by muse, mutect2
- PGBD5 | c.270G>C p.W90C (on ENST00000525115; = p.W159C on NM_001258311.2) | Missense Mutation (SNP) | VAF 83/683 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PHF8 | c.2268G>T p.E756D (on ENST00000357988 / NM_001184896.1; = p.E720D on NM_015107.3) | Missense Mutation (SNP) | VAF 40/381 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PHKA2 | c.3083C>G p.S1028C | Missense Mutation (SNP) | VAF 41/801 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- PNP | c.368A>T p.K123M | Missense Mutation (SNP) | VAF 156/643 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- PNPLA6 | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 11/281 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.168); called by muse, mutect2
- POLR2B | c.1932A>T p.K644N | Missense Mutation (SNP) | VAF 27/378 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.722); called by muse, mutect2
- PPFIA2 | c.386C>G p.A129G | Missense Mutation (SNP) | VAF 24/353 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PPFIA4 | c.2442G>T p.Q814H (on ENST00000447715; = p.Q815H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/533 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- PPP1R18 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 76/582 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- PPP1R3G | c.668T>A p.V223E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PRAMEF8 | c.877T>A p.S293T | Missense Mutation (SNP) | VAF 143/1227 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- PRF1 | c.1178G>T p.C393F | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRPF40A | c.2971G>A p.D991N | Missense Mutation (SNP) | VAF 82/1108 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- PRPS1L1 | c.405G>T p.Q135H | Missense Mutation (SNP) | VAF 115/743 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- PRRC1 | c.733G>T p.D245Y | Missense Mutation (SNP) | VAF 63/519 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSG1 | c.163G>T p.V55F | Missense Mutation (SNP) | VAF 66/523 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- PSG4 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 53/502 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PSG7 | c.503C>G p.T168S | Missense Mutation (SNP) | VAF 71/578 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- PXDNL | c.4178C>T p.A1393V | Missense Mutation (SNP) | VAF 82/499 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PYHIN1 | c.297A>T p.K99N | Missense Mutation (SNP) | VAF 19/561 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); called by muse, mutect2
- RAD51AP2 | c.2705A>G p.Y902C | Missense Mutation (SNP) | VAF 20/251 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2
- RGS7 | c.227-1G>A p.X76_splice | Splice Site (SNP) | VAF 84/1247 reads (7%) | called by muse, mutect2
- RINL | c.1304G>C p.R435T (on ENST00000591812 / NM_001195833.2; = p.R321T on NM_198445.4) | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2
- RIPK1 | c.472G>T p.G158C | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF146 | c.777A>C p.E259D (on ENST00000368314 / NM_001242850.2; = p.E258D on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/930 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2
- RXRA | c.1376A>T p.H459L | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SAFB | c.1945C>T p.R649* | Nonsense Mutation (SNP) | VAF 29/289 reads (10%) | called by muse, mutect2, varscan2
- SAMSN1 | c.76A>G p.N26D | Missense Mutation (SNP) | VAF 119/741 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- SATB2 | c.193G>T p.V65F | Missense Mutation (SNP) | VAF 52/1226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- SCG2 | c.1471C>T p.Q491* | Nonsense Mutation (SNP) | VAF 31/406 reads (8%) | called by muse, mutect2
- SCN10A | c.1406G>T p.G469V | Missense Mutation (SNP) | VAF 48/716 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- SCN4A | c.1489G>C p.D497H | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.213); called by muse, mutect2
- SCOC | c.246C>A p.D82E (on ENST00000608372; = p.D45E on NM_032547.3) | Missense Mutation (SNP) | VAF 20/599 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- SERPINE1 | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SERPINE1 | c.595A>G p.K199E | Missense Mutation (SNP) | VAF 58/389 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- SFMBT2 | c.1373C>A p.S458Y | Missense Mutation (SNP) | VAF 18/552 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SH2D4B | c.908T>A p.V303D (on ENST00000646907; = p.V302D on NM_207372.2) | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); called by muse, mutect2
- SHOC1 | c.3181C>A p.L1061I | Missense Mutation (SNP) | VAF 40/658 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SHTN1 | c.1210G>T p.D404Y | Missense Mutation (SNP) | VAF 16/494 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SI | c.680T>A p.L227* | Nonsense Mutation (SNP) | VAF 30/584 reads (5%) | called by muse, mutect2
- SIGLEC1 | c.1876G>T p.V626L | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SIGLEC15 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- SLC18A3 | c.683C>G p.A228G | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.933); called by muse, mutect2
- SLC22A8 | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.21); called by muse, mutect2
- SLC27A4 | c.1894G>T p.A632S | Missense Mutation (SNP) | VAF 82/330 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- SLC4A8 | c.2542G>T p.V848F | Missense Mutation (SNP) | VAF 98/960 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A8 | c.1192G>A p.V398M | Missense Mutation (SNP) | VAF 33/507 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.027); called by muse, mutect2
- SLCO2B1 | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.03); called by muse, varscan2
- SMC1A | c.1577C>T p.T526I | Missense Mutation (SNP) | VAF 84/1006 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.042); called by muse, mutect2
- SNTG1 | c.900C>A p.D300E | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.97); called by muse, mutect2
- SNTG2 | c.594C>A p.A198= | Splice Region (SNP) | VAF 23/336 reads (7%) | called by muse, mutect2
- SORCS1 | c.3296G>T p.S1099I | Missense Mutation (SNP) | VAF 36/402 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2
- SPAM1 | c.1504G>T p.D502Y | Missense Mutation (SNP) | VAF 39/401 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SPATA31A6 | c.3772C>A p.L1258M | Missense Mutation (SNP) | VAF 316/1932 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SUFU | c.962A>T p.K321I | Missense Mutation (SNP) | VAF 44/872 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2
- SVIL | c.2667G>T p.M889I (on ENST00000355867 / NM_021738.3; = p.M463I on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/449 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TBC1D25 | c.1283A>T p.E428V | Missense Mutation (SNP) | VAF 22/599 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TBX4 | c.164T>A p.V55D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by mutect2, varscan2
- TECRL | c.851C>A p.P284Q | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2
- TENM2 | c.4369C>A p.Q1457K (on ENST00000518659 / NM_001122679.2; = p.Q1218K on NM_001080428.3) | Missense Mutation (SNP) | VAF 56/490 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- TEX13A | c.799C>A p.L267I | Missense Mutation (SNP) | VAF 44/656 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.046); called by muse, mutect2
- THBS4 | c.374A>G p.H125R | Missense Mutation (SNP) | VAF 29/328 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.24); called by muse, mutect2
- TMEM178B | c.805T>A p.C269S | Missense Mutation (SNP) | VAF 33/412 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM185A | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 73/1264 reads (6%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.621); called by muse, mutect2
- TMEM54 | c.441C>G p.F147L | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- TMPRSS3 | c.869T>C p.I290T | Missense Mutation (SNP) | VAF 35/724 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- TPRX1 | c.29A>T p.E10V | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- TRBV6-1 | c.190C>A p.L64M | Missense Mutation (SNP) | VAF 62/639 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRO | c.2257G>T p.G753C | Missense Mutation (SNP) | VAF 54/414 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TRPM2 | c.1494G>T p.E498D | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.009); called by muse, varscan2
- TTN | c.87812G>C p.G29271A (on ENST00000591111; = p.G21847A on NM_003319.4) | Missense Mutation (SNP) | VAF 47/1182 reads (4%) | PolyPhen benign (0.003); called by muse, mutect2
- TTN | c.12247T>G p.C4083G (on ENST00000591111; = p.C4037G on NM_003319.4) | Missense Mutation (SNP) | VAF 50/450 reads (11%) | called by muse, mutect2, varscan2
- UGT3A1 | c.1295+1G>T p.X432_splice | Splice Site (SNP) | VAF 48/370 reads (13%) | called by muse, mutect2, varscan2
- UNC5C | c.1594G>T p.A532S | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.837); called by muse, mutect2
- USH2A | c.12420T>G p.C4140W | Missense Mutation (SNP) | VAF 89/559 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USH2A | c.10624G>T p.E3542* | Nonsense Mutation (SNP) | VAF 57/1332 reads (4%) | called by muse, mutect2
- USH2A | c.2643G>T p.Q881H | Missense Mutation (SNP) | VAF 126/1430 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.018); called by muse, mutect2
- USP20 | c.1489C>G p.P497A | Missense Mutation (SNP) | VAF 17/295 reads (6%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.589); called by muse, mutect2
- VCAM1 | c.599A>T p.H200L | Missense Mutation (SNP) | VAF 54/535 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.027); called by muse, mutect2
- VCAN | c.1883G>T p.S628I | Missense Mutation (SNP) | VAF 122/1304 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.034); called by muse, mutect2
- VGLL3 | c.657C>G p.Y219* | Nonsense Mutation (SNP) | VAF 57/612 reads (9%) | called by muse, mutect2
- VWA3B | c.1022G>C p.W341S | Missense Mutation (SNP) | VAF 70/427 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- VWA5B1 | c.2135C>A p.P712H | Missense Mutation (SNP) | VAF 32/332 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.708); called by muse, mutect2
- VWA5B1 | c.2136C>A p.P712= | Splice Region (SNP) | VAF 34/336 reads (10%) | called by muse, mutect2
- WDR44 | c.2183C>A p.T728K | Missense Mutation (SNP) | VAF 21/308 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- WDSUB1 | c.1349T>G p.L450R | Missense Mutation (SNP) | VAF 43/633 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- XIRP1 | c.5416C>A p.H1806N | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- XIRP2 | c.4252C>A p.P1418T (on ENST00000628543; = p.P1593T on NM_152381.6) | Missense Mutation (SNP) | VAF 40/371 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- XPO6 | c.28del p.A10Hfs*5 | Frame Shift Del (DEL) | VAF 52/545 reads (10%) | called by mutect2, pindel
- ZFP42 | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- ZHX1 | c.2564G>A p.S855N | Missense Mutation (SNP) | VAF 51/324 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ZIM2 | c.403C>A p.L135I | Missense Mutation (SNP) | VAF 21/272 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.073); called by muse, mutect2
- ZNF331 | c.1219G>T p.G407W | Missense Mutation (SNP) | VAF 44/397 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF41 | c.56G>T p.R19L | Missense Mutation (SNP) | VAF 34/398 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- ZNF418 | c.1934G>T p.R645M | Missense Mutation (SNP) | VAF 58/493 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ZNF511-PRAP1 | c.752C>A p.P251H | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF638 | c.5047G>T p.V1683L | Missense Mutation (SNP) | VAF 66/457 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- ZNF653 | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC12 | c.396G>A p.L132= | Silent (SNP) | VAF 48/263 reads (18%) | catalogued as COSV100252222; called by muse, mutect2, varscan2
- AC092143.1 | c.2199G>T p.T733= | Silent (SNP) | VAF 102/558 reads (18%) | catalogued as rs773849361; called by mutect2, varscan2
- ACAA1 | c.24G>T p.L8= | Silent (SNP) | VAF 20/197 reads (10%) | called by muse, mutect2, varscan2
- AL645922.1 | c.2094C>T p.T698= | Silent (SNP) | VAF 92/415 reads (22%) | called by muse, mutect2, varscan2
- ANK1 | c.5064C>A p.T1688= | Silent (SNP) | VAF 24/173 reads (14%) | catalogued as COSV55873686; called by muse, mutect2, varscan2
- ANO3 | c.648G>T p.T216= | Silent (SNP) | VAF 67/826 reads (8%) | catalogued as COSV56808334; called by muse, mutect2
- ARHGAP6 | c.735C>A p.I245= | Silent (SNP) | VAF 8/117 reads (7%) | catalogued as COSV57291441; called by muse, mutect2
- ARHGEF12 | c.1779G>A p.K593= | Silent (SNP) | VAF 14/360 reads (4%) | catalogued as rs1263427038; called by muse, mutect2
- ATF6 | c.783A>C p.G261= | Silent (SNP) | VAF 42/1148 reads (4%) | called by muse, mutect2
- C1QA | c.366G>T p.R122= | Silent (SNP) | VAF 60/618 reads (10%) | called by muse, mutect2
- C1orf141 | c.1092C>A p.A364= | Silent (SNP) | VAF 88/1110 reads (8%) | called by muse, mutect2
- CACNA1F | c.5718G>A p.E1906= | Silent (SNP) | VAF 7/162 reads (4%) | called by muse, mutect2
- CATSPERE | c.1284A>G p.T428= | Silent (SNP) | VAF 73/766 reads (10%) | called by muse, mutect2
- CCDC166 | c.555G>A p.E185= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as rs1431651622; called by muse, mutect2, varscan2
- CCNF | c.1047G>T p.R349= | Silent (SNP) | VAF 29/233 reads (12%) | catalogued as rs144631476; called by muse, mutect2, varscan2
- CCR3 | c.525A>G p.E175= | Silent (SNP) | VAF 24/474 reads (5%) | called by muse, mutect2
- CDH9 | c.1467C>A p.A489= | Silent (SNP) | VAF 88/615 reads (14%) | catalogued as COSV50333570; called by muse, mutect2, varscan2
- CDX4 | c.144G>T p.P48= | Silent (SNP) | VAF 17/255 reads (7%) | called by muse, mutect2
- CENPT | c.1119C>G p.S373= | Silent (SNP) | VAF 51/377 reads (14%) | called by muse, mutect2, varscan2
- CFAP298 | c.759C>T p.L253= | Silent (SNP) | VAF 37/360 reads (10%) | called by muse, mutect2
- CFAP54 | c.6585A>G p.Q2195= | Silent (SNP) | VAF 40/836 reads (5%) | called by muse, mutect2
- CHST9 | c.1236G>A p.Q412= | Silent (SNP) | VAF 58/919 reads (6%) | called by muse, mutect2
- CSMD3 | c.1566G>A p.K522= (on ENST00000297405 / NM_001363185.1; = p.K418= on NM_052900.3) | Silent (SNP) | VAF 220/1443 reads (15%) | catalogued as rs774142265; called by muse, mutect2, varscan2
- CYP2J2 | c.1066C>A p.R356= | Silent (SNP) | VAF 67/627 reads (11%) | catalogued as COSV100967928; called by muse, mutect2, varscan2
- DACT1 | c.1560G>T p.P520= | Silent (SNP) | VAF 42/293 reads (14%) | called by muse, mutect2, varscan2
- DHX38 | c.1713A>G p.E571= | Silent (SNP) | VAF 27/447 reads (6%) | called by muse, mutect2
- DOCK9 | c.1569A>T p.P523= (on ENST00000376460 / NM_001366676.2; = p.P524= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/590 reads (7%) | called by muse, mutect2
- EFCAB1 | c.36C>A p.T12= | Silent (SNP) | VAF 38/458 reads (8%) | called by muse, mutect2
- ENPP1 | c.2199C>A p.T733= | Silent (SNP) | VAF 68/1016 reads (7%) | called by muse, mutect2
- FAM171A1 | c.1282C>A p.R428= | Silent (SNP) | VAF 18/180 reads (10%) | catalogued as COSV65316976; called by muse, mutect2
- GLYATL3 | c.585T>C p.D195= | Silent (SNP) | VAF 52/801 reads (6%) | called by muse, mutect2
- GRM1 | c.2001C>A p.S667= | Silent (SNP) | VAF 8/134 reads (6%) | catalogued as COSV51129185; called by muse, mutect2
- GTPBP2 | c.471C>T p.T157= | Silent (SNP) | VAF 84/570 reads (15%) | catalogued as rs377567561; called by muse, mutect2, varscan2
- HFM1 | c.3369T>C p.S1123= | Silent (SNP) | VAF 34/283 reads (12%) | called by muse, varscan2
- HSD3B1 | c.399C>A p.S133= | Silent (SNP) | VAF 41/421 reads (10%) | called by muse, mutect2, varscan2
- ICAM1 | c.1590G>T p.T530= | Silent (SNP) | VAF 20/85 reads (24%) | called by muse, mutect2, varscan2
- IRX4 | c.192C>A p.L64= | Silent (SNP) | VAF 31/328 reads (9%) | called by muse, mutect2
- ITIH6 | c.1908A>C p.S636= | Silent (SNP) | VAF 29/366 reads (8%) | called by muse, mutect2
- JAKMIP1 | c.297G>T p.A99= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV51522135; called by muse, mutect2
- KANSL1 | c.3126G>C p.A1042= (on ENST00000574590 / NM_001193465.2; = p.A1043= on NM_015443.4) | Silent (SNP) | VAF 19/86 reads (22%) | called by muse, mutect2, varscan2
- KCNA1 | c.129C>A p.I43= | Silent (SNP) | VAF 36/340 reads (11%) | called by muse, mutect2, varscan2
- KDM1A | c.492T>C p.N164= | Silent (SNP) | VAF 9/184 reads (5%) | called by muse, mutect2
- KIAA2026 | c.2946A>T p.P982= | Silent (SNP) | VAF 15/317 reads (5%) | called by muse, mutect2
- KIF4A | c.2991C>G p.L997= | Silent (SNP) | VAF 34/470 reads (7%) | called by muse, mutect2
- LAMC3 | c.465C>T p.G155= | Silent (SNP) | VAF 24/312 reads (8%) | called by muse, mutect2
- LSAMP | c.687C>A p.A229= | Silent (SNP) | VAF 46/547 reads (8%) | called by muse, mutect2
- MAP3K19 | c.2529A>G p.L843= | Silent (SNP) | VAF 32/148 reads (22%) | called by muse, mutect2, varscan2
- MPC1L | c.180G>T p.A60= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- MXRA5 | c.2583C>A p.A861= | Silent (SNP) | VAF 64/624 reads (10%) | called by muse, mutect2, varscan2
- MYCBP2 | c.6996T>C p.Y2332= (on ENST00000357337; = p.Y2370= on NM_015057.5) | Silent (SNP) | VAF 62/499 reads (12%) | called by muse, mutect2, varscan2
- NAV2 | c.6456G>T p.R2152= (on ENST00000396087 / NM_001244963.2; = p.R2093= on NM_145117.5) | Silent (SNP) | VAF 22/524 reads (4%) | called by muse, mutect2
- NKRF | c.390C>A p.A130= | Silent (SNP) | VAF 42/662 reads (6%) | called by muse, mutect2
- OPN1LW | c.69C>A p.T23= | Silent (SNP) | VAF 20/506 reads (4%) | called by muse, mutect2
- OR10A2 | c.441C>A p.T147= | Silent (SNP) | VAF 117/695 reads (17%) | called by muse, mutect2, varscan2
- OR2M4 | c.261T>A p.S87= | Silent (SNP) | VAF 49/470 reads (10%) | called by muse, mutect2, varscan2
- OR9A2 | c.360G>T p.V120= | Silent (SNP) | VAF 104/585 reads (18%) | called by muse, mutect2, varscan2
- OR9G4 | c.246G>T p.L82= | Silent (SNP) | VAF 72/818 reads (9%) | called by muse, mutect2
- PCDH15 | c.2925T>G p.P975= | Silent (SNP) | VAF 93/809 reads (11%) | called by muse, mutect2, varscan2
- PCDH9 | c.3105C>T p.F1035= | Silent (SNP) | VAF 69/453 reads (15%) | called by muse, mutect2, varscan2
- PCDHB12 | c.2013G>T p.L671= | Silent (SNP) | VAF 35/371 reads (9%) | called by muse, mutect2, varscan2
- PCDHB9 | c.1746G>T p.P582= | Silent (SNP) | VAF 45/562 reads (8%) | called by muse, mutect2, varscan2
- PCDHGA1 | c.198C>A p.I66= | Silent (SNP) | VAF 29/267 reads (11%) | called by muse, mutect2, varscan2
- PGBD2 | c.1098G>A p.K366= | Silent (SNP) | VAF 48/1162 reads (4%) | called by muse, mutect2
- PIGN | c.264A>G p.T88= | Silent (SNP) | VAF 42/736 reads (6%) | called by muse, mutect2
- PLA2G2C | c.96G>C p.G32= | Silent (SNP) | VAF 76/620 reads (12%) | called by muse, mutect2, varscan2
- PLCE1 | c.2970A>T p.A990= | Silent (SNP) | VAF 40/355 reads (11%) | called by muse, mutect2, varscan2
- POU5F1B | c.378G>A p.K126= | Silent (SNP) | VAF 42/551 reads (8%) | called by muse, mutect2
- PPARGC1A | c.2025G>A p.E675= | Silent (SNP) | VAF 55/542 reads (10%) | called by muse, mutect2, varscan2
- PXMP4 | c.472C>T p.L158= | Silent (SNP) | VAF 54/540 reads (10%) | called by muse, mutect2
- RBM33 | c.3327C>T p.T1109= | Silent (SNP) | VAF 28/249 reads (11%) | catalogued as rs1563183054; called by muse, mutect2, varscan2
- RCC1L | c.903C>T p.D301= | Silent (SNP) | VAF 126/957 reads (13%) | catalogued as rs1255668211; called by muse, mutect2, varscan2
- RUNX1 | c.615G>T p.R205= (on ENST00000344691 / NM_001001890.3; = p.R232= on NM_001754.5) | Silent (SNP) | VAF 12/254 reads (5%) | called by muse, mutect2
- SETBP1 | c.3819G>T p.T1273= | Silent (SNP) | VAF 94/1014 reads (9%) | catalogued as COSV99955039; called by muse, mutect2
- SIMC1 | c.984A>C p.G328= (on ENST00000443967 / NM_001308196.1; = p.G347= on NM_001308195.2) | Silent (SNP) | VAF 17/298 reads (6%) | called by muse, mutect2
- SLITRK3 | c.1068C>T p.N356= | Silent (SNP) | VAF 49/514 reads (10%) | catalogued as rs1264832256; called by muse, mutect2
- SLITRK4 | c.978C>G p.L326= | Silent (SNP) | VAF 52/528 reads (10%) | called by muse, mutect2, varscan2
- SMO | c.594T>A p.V198= | Silent (SNP) | VAF 77/546 reads (14%) | called by muse, mutect2, varscan2
- SPHKAP | c.4281T>C p.P1427= | Silent (SNP) | VAF 24/416 reads (6%) | catalogued as rs1437163680; called by muse, mutect2
- SPRY1 | c.720C>T p.S240= | Silent (SNP) | VAF 21/702 reads (3%) | catalogued as rs1357390540; called by muse, mutect2
- SYT13 | c.306G>C p.L102= | Silent (SNP) | VAF 44/671 reads (7%) | called by muse, mutect2
- TBX3 | c.951C>A p.L317= (on ENST00000257566 / NM_016569.4; = p.L297= on NM_005996.4) | Silent (SNP) | VAF 40/858 reads (5%) | called by muse, mutect2
- TFAP2D | c.330C>A p.P110= | Silent (SNP) | VAF 42/528 reads (8%) | catalogued as COSV99148172; called by muse, mutect2
- TMEM26 | c.549G>T p.G183= | Silent (SNP) | VAF 40/834 reads (5%) | called by muse, mutect2
- TROAP | c.2037G>T p.P679= | Silent (SNP) | VAF 17/154 reads (11%) | catalogued as rs199576676; called by muse, mutect2, varscan2
- TSHZ3 | c.2709C>T p.L903= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV99552961; called by muse, mutect2, varscan2
- TTN | c.95076C>T p.A31692= (on ENST00000591111; = p.A24268= on NM_003319.4) | Silent (SNP) | VAF 26/524 reads (5%) | called by muse, mutect2
- UBE4A | c.1065A>G p.P355= (on ENST00000252108 / NM_001204077.2; = p.P362= on NM_004788.4) | Silent (SNP) | VAF 48/374 reads (13%) | catalogued as rs1361277516; called by muse, mutect2, varscan2
- VWA5B1 | c.3462G>A p.L1154= (on ENST00000375079; = p.L1149= on NM_001039500.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 92/665 reads (14%) | called by muse, mutect2, varscan2
- ZNF180 | c.1839C>T p.S613= | Silent (SNP) | VAF 96/561 reads (17%) | called by muse, mutect2, varscan2
- ZNF469 | c.4734C>T p.P1578= (on ENST00000437464; = p.P1606= on NM_001367624.2) | Silent (SNP) | VAF 52/353 reads (15%) | called by muse, mutect2, varscan2
- ZNF831 | c.219C>A p.P73= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- AC103993.1 | n.60G>A | RNA (SNP) | VAF 85/529 reads (16%) | called by muse, mutect2, varscan2
- AC103993.1 | n.61G>T | RNA (SNP) | VAF 87/535 reads (16%) | catalogued as rs755260055; called by muse, mutect2, varscan2
- AC103993.1 | n.142G>T | RNA (SNP) | VAF 71/470 reads (15%) | called by muse, mutect2, varscan2
- ACADM | c.388-9C>T | Intron (SNP) | VAF 61/856 reads (7%) | called by muse, mutect2
- ADAM33 | c.2241-25C>A | Intron (SNP) | VAF 78/378 reads (21%) | called by muse, mutect2, varscan2
- AIFM1 | c.-19C>G | 5'UTR (SNP) | VAF 30/592 reads (5%) | called by muse, mutect2
- ALMS1P1 | chr2:73700721 C>A | 3'Flank (SNP) | VAF 20/464 reads (4%) | called by muse, mutect2
- ANKRD26P1 | n.707C>T | RNA (SNP) | VAF 29/456 reads (6%) | called by muse, mutect2
- ARHGEF4 | c.-109+40G>T | Intron (SNP) | VAF 35/160 reads (22%) | catalogued as COSV100388024; called by muse, mutect2, varscan2
- AZGP1 | chr7:99980832 C>A | 5'Flank (SNP) | VAF 64/1086 reads (6%) | called by muse, mutect2
- B4GALNT1 | c.*1863C>A | 3'UTR (SNP) | VAF 27/296 reads (9%) | called by muse, mutect2
- BTNL3 | c.-57C>A | 5'UTR (SNP) | VAF 40/619 reads (6%) | called by muse, mutect2
- C11orf16 | c.325-444C>A | Intron (SNP) | VAF 27/271 reads (10%) | catalogued as rs761438926; called by muse, mutect2, varscan2
- C1orf220 | n.91-223G>C | Intron (SNP) | VAF 28/402 reads (7%) | called by muse, mutect2
- C7orf66 | n.266C>A | RNA (SNP) | VAF 132/1082 reads (12%) | called by muse, mutect2, varscan2
- CACNA1D | c.1478+341G>T | Intron (SNP) | VAF 33/247 reads (13%) | catalogued as COSV99856205; called by muse, mutect2, varscan2
- CCDC74A | c.250+55T>A | Intron (SNP) | VAF 15/346 reads (4%) | called by muse, mutect2
- CDC20B | c.126+2021C>T | Intron (SNP) | VAF 70/1038 reads (7%) | catalogued as rs751356503; called by muse, mutect2
- CDON | c.*4732G>T | 3'UTR (SNP) | VAF 83/779 reads (11%) | called by muse, mutect2, varscan2
- CELF4 | c.1165+16T>C | Intron (SNP) | VAF 22/212 reads (10%) | catalogued as rs147319332, COSV58454641; called by muse, mutect2
- CFL2 | c.*1540C>T | 3'UTR (SNP) | VAF 175/1428 reads (12%) | catalogued as rs549126569; called by muse, mutect2, varscan2
- CORIN | c.2068+139C>G | Intron (SNP) | VAF 46/646 reads (7%) | called by muse, mutect2
- CTSL3P | n.466G>T | RNA (SNP) | VAF 32/576 reads (6%) | called by muse, mutect2
- DCHS2 | n.289A>G | RNA (SNP) | VAF 43/662 reads (6%) | called by muse, mutect2
- DNAJC18 | c.952+882A>T | Intron (SNP) | VAF 24/281 reads (9%) | called by muse, mutect2
- DPY19L2P1 | n.1725A>T | RNA (SNP) | VAF 90/791 reads (11%) | called by muse, mutect2, varscan2
- DPY19L2P1 | n.465T>A | RNA (SNP) | VAF 22/541 reads (4%) | called by muse, mutect2
- EIF5 | c.440-461A>T | Intron (SNP) | VAF 63/353 reads (18%) | called by muse, mutect2, varscan2
- ELP2 | chr18:36129888 G>T | 5'Flank (SNP) | VAF 84/586 reads (14%) | called by muse, mutect2, varscan2
- ERCC6 | c.1398-23T>A | Intron (SNP) | VAF 38/888 reads (4%) | called by muse, mutect2
- FAM161A | c.*334G>A | 3'UTR (SNP) | VAF 72/630 reads (11%) | called by muse, mutect2, varscan2
- FGF13 | c.403-32080G>T | Intron (SNP) | VAF 39/540 reads (7%) | called by muse, mutect2
- FOXP3 | c.*21G>T | 3'UTR (SNP) | VAF 16/190 reads (8%) | called by muse, mutect2
- GALNTL6 | c.-8C>T | 5'UTR (SNP) | VAF 102/703 reads (15%) | catalogued as rs1238412569; called by muse, mutect2, varscan2
- GRIP2 | c.857+45del | Intron (DEL) | VAF 17/191 reads (9%) | called by mutect2, pindel
- HAO2 | c.-8-382G>T | Intron (SNP) | VAF 34/465 reads (7%) | catalogued as rs749821293; called by muse, mutect2
- HERC4 | c.1070-2550A>G | Intron (SNP) | VAF 16/356 reads (4%) | called by muse, mutect2
- HINT1 | c.217-1196A>G | Intron (SNP) | VAF 31/402 reads (8%) | called by muse, mutect2
- KLHL4 | c.*17C>T | 3'UTR (SNP) | VAF 45/506 reads (9%) | called by muse, mutect2
- KYNU | c.374-7669G>T | Intron (SNP) | VAF 31/770 reads (4%) | called by muse, mutect2
- LINGO1-AS1 | n.152G>T | RNA (SNP) | VAF 73/466 reads (16%) | catalogued as rs1192073113; called by muse, mutect2, varscan2
- LMF1 | c.514+2451C>T | Intron (SNP) | VAF 14/138 reads (10%) | catalogued as rs1008295898; called by muse, mutect2, varscan2
- LNPK | c.1055-1941A>C | Intron (SNP) | VAF 33/525 reads (6%) | called by muse, mutect2
- LRSAM1 | c.252+42G>T | Intron (SNP) | VAF 24/286 reads (8%) | called by muse, mutect2
- MARF1 | c.4814-41G>T | Intron (SNP) | VAF 20/164 reads (12%) | catalogued as rs1319539295; called by muse, mutect2, varscan2
- MBD5 | c.2845+503C>A | Intron (SNP) | VAF 34/350 reads (10%) | called by muse, mutect2
- MEIS1 | c.*124A>G | 3'UTR (SNP) | VAF 65/380 reads (17%) | called by mutect2, varscan2
- MIR202 | n.65G>T | RNA (SNP) | VAF 39/367 reads (11%) | called by muse, mutect2, varscan2
- NDUFA10 | c.999+7900G>T | Intron (SNP) | VAF 32/608 reads (5%) | called by muse, mutect2
- NRG3 | c.824-191995G>C | Intron (SNP) | VAF 68/582 reads (12%) | called by muse, mutect2, varscan2
- PDP1 | c.-132C>T | 5'UTR (SNP) | VAF 34/134 reads (25%) | called by muse, mutect2, varscan2
- PMM2 | c.640-12G>C | Intron (SNP) | VAF 88/659 reads (13%) | catalogued as rs375325546; called by muse, mutect2, varscan2
- POU2F3 | c.362-1182C>A | Intron (SNP) | VAF 78/620 reads (13%) | called by muse, mutect2, varscan2
- RPL10 | c.492+24C>A | Intron (SNP) | VAF 44/1131 reads (4%) | called by muse, mutect2
- SEMA3D | c.861+5014G>C | Intron (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- SFTPB | c.857-14G>A | Intron (SNP) | VAF 28/476 reads (6%) | catalogued as rs1159059618; called by muse, mutect2
- SLC25A29 | c.78+85G>T | Intron (SNP) | VAF 31/254 reads (12%) | called by muse, mutect2, varscan2
- SLC36A4 | c.-5G>A | 5'UTR (SNP) | VAF 17/177 reads (10%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23824C>A | Intron (SNP) | VAF 56/429 reads (13%) | catalogued as rs916163928; called by muse, mutect2, varscan2
- SNURFL | n.240G>A | RNA (SNP) | VAF 16/516 reads (3%) | called by muse, mutect2
- SOCS3 | c.-4C>T | 5'UTR (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- SPATA31C2 | n.3465C>A | RNA (SNP) | VAF 82/804 reads (10%) | called by muse, mutect2, varscan2
- TAF10 | c.*1480G>C | 3'UTR (SNP) | VAF 137/1215 reads (11%) | called by muse, mutect2, varscan2
- TMEM135 | c.*4102G>T | 3'UTR (SNP) | VAF 153/696 reads (22%) | called by muse, varscan2
- TMEM135 | c.*4103G>T | 3'UTR (SNP) | VAF 156/700 reads (22%) | called by muse, varscan2
- TMEM59L | c.664+249A>G | Intron (SNP) | VAF 21/452 reads (5%) | called by muse, mutect2
- UQCRB | c.*1816A>G | 3'UTR (SNP) | VAF 98/1056 reads (9%) | catalogued as rs749779841; called by muse, mutect2
- ZNF99 | c.*3173A>T | 3'UTR (SNP) | VAF 26/173 reads (15%) | called by muse, mutect2, varscan2
- ZNF99 | c.*2771C>A | 3'UTR (SNP) | VAF 21/164 reads (13%) | called by muse, mutect2, varscan2
